Gene-level copy-number profile of tumor specimen ALCH-ABEI-TTP1-A from ALCHEMIST case ALCH-ABEI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.3 years (28,596 days).
Specimen ALCH-ABEI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65dec6f2-da82-4cf0-af0a-e1cc4b4e0d7a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABEI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/a6d2fe30-8994-4f49-a13a-580cc91bd9d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 11,433; copy number 2: 45,516; copy number 3: 1,625; copy number 4: 107; copy number 5: 22; copy number 7: 53; copy number 8: 13; copy number 9: 54; copy number 10: 32; copy number 14: 32.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:39,297,605–39,297,711, 1 gene (within-gene range 0–2): RNU6-32P.
- chr4:119,405,523–119,454,638, 1 gene (within-gene range 0–2): GTF2IP12.
- chr4:119,434,005–119,434,108, 1 gene: RNU6-1217P.
- chr6:167,208,631–167,208,897, 1 gene: AL353747.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr11:440,399–440,693, 1 gene (within-gene range 0–1): RN7SL838P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 206 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:151,949,571–154,560,440, 22 genes, copy number 5–8: LINC01933, AC008571.2, NMUR2, AC008571.1, LINC01470, GRIA1, RN7SL177P, LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1, CIR1P1.
- chr5:159,100,483–163,437,326, 46 genes, copy number 5–10 (within-gene range 3–10): LINC02202, AC134043.3, RNF145, AC134043.2, LINC01932, AC134043.1, UBLCP1, AC008691.1, IL12B, RNU4ATAC2P, LINC01845, LINC01847, ADRA1B, GAPDHP40, Y_RNA, TTC1, AC068657.1, PWWP2A, FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A, ATP10B, AC008456.1, AC011363.1, LINC02159, GABRB2, GABRA6, AC091944.1, GLRXP3, GABRA1, LINC01202, GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6.
- chr5:164,119,098–164,234,097, 2 genes, copy number 5: AC008662.1, AC008662.2.
- chr12:50,756,892–50,757,433, 1 gene, copy number 8: AC013244.1.
- chr12:64,452,090–70,434,292, 135 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
